Gene-level copy-number profile of tumor specimen C3L-06641-03 from CPTAC case C3L-06641, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 76.1 years (27,780 days).
Specimen C3L-06641-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5f8e85c8-9f75-4536-9e09-b095aacfd524.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06641-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/c52a281b-dde6-4e09-9c59-ece88d03f857

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 556; copy number 2: 22,873; copy number 3: 19,402; copy number 4: 11,974; copy number 5: 3,085; copy number 6: 510; copy number 7: 33; copy number 8: 56; copy number 9: 58; copy number 10: 11; copy number 11: 80; copy number 12: 2; copy number 13: 43; copy number 14: 4; copy number 15: 73; copy number 16: 25; copy number 17: 5; copy number 18: 2; copy number 19: 25; copy number 20: 5; copy number 21: 2; copy number 22: 27; copy number 27: 11; copy number 42: 4; copy number 52: 38.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:96,979,528–96,979,629, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,099 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–827,796, 37 genes, copy number 6–8 (within-gene range 3–14): OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AL669831.3, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3.
- chr1:143,874,793–143,905,966, 3 genes, copy number 6: FCGR1CP, H2BP2, H3-2.
- chr1:221,508,559–236,764,631, 373 genes, copy number 5 (broad region; genes not listed).
- chr1:237,862,175–239,250,818, 17 genes, copy number 5: AL359924.1, ZP4, AL590396.1, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL590135.1, AC093426.1.
- chr1:239,915,439–248,937,043, 236 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr4:49,096–10,697,661, 298 genes, copy number 5 (broad region; genes not listed).
- chr4:27,964,517–28,824,211, 6 genes, copy number 6: AC007106.1, AC093791.1, AC097480.1, AC097480.2, RN7SL101P, MESTP3.
- chr4:138,425,523–140,154,184, 36 genes, copy number 5 (within-gene range 4–5): LINC00500, AC105416.1, AC098859.1, AC098859.2, AC093766.1, AC109927.1, AC109927.2, NOCT, ELF2, RNU6-531P, RN7SL382P, PPP1R14BP3, Metazoa_SRP, RN7SL311P, Y_RNA, RNU6-506P, RNU6-1074P, MGARP, NDUFC1, NAA15, RNU6-1214P, AC097376.3, AC097376.2, AC097376.1, RAB33B, SETD7, FTH1P24, AC112236.2, AC112236.3, AC112236.1, MGST2, RN7SKP237, H3P16, MAML3, AC108053.1, RN7SKP253.
- chr7:56,940,341–57,074,664, 6 genes, copy number 5: AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1.
- chr8:6,977,649–7,018,297, 5 genes, copy number 5: DEFA1, DEFT1P, DEFA1B, DEFT1P2, DEFA3.
- chr8:90,791,741–143,276,403, 731 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:101,449,801–103,018,488, 15 genes, copy number 5: AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20, GRIN3A, PPP3R2, MTND3P4, ARL2BPP7, RNU6-329P, AL442644.1, LINC00587, ZYG11AP1, AL365396.1, CYLC2.
- chr11:59,416,969–60,396,596, 41 genes, copy number 6 (within-gene range 4–6): OR5A2, OR5A1, OR4D6, OR4D10, OR4D8P, OR4D11, OR4D9, OR4D7P, LINC02739, AP000442.1, OSBP, MIR3162, PATL1, AP000640.2, RN7SKP192, OR10V1, STX3, OR10Y1P, OR10V3P, OR10V2P, AP000640.1, FABP5P7, MRPL16, CBLIF, TCN1, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A, MS4A4A, MS4A4E, MIR6503, MS4A6E, MS4A7.
- chr11:66,744,451–66,843,516, 1 gene, copy number 11 (within-gene range 4–11): C11orf80.
- chr11:66,842,835–71,845,245, 175 genes, copy number 5–22 (broad region; genes not listed).
- chr12:12,310–34,249,958, 834 genes, copy number 5–6 (broad region; genes not listed).
- chr12:56,316,223–56,596,193, 17 genes, copy number 5 (within-gene range 2–5): PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4, RBMS2, RNU6-343P.
- chr12:63,558,913–66,343,643, 82 genes, copy number 6–19 (broad region; genes not listed).
- chr12:67,065,018–71,118,247, 87 genes, copy number 6–52 (within-gene range 2–52) (broad region; genes not listed).
- chr12:72,087,266–72,728,844, 5 genes, copy number 7 (within-gene range 2–7): TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr13:70,923,664–74,259,976, 33 genes, copy number 9–20: MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402.
- chr13:74,289,100–74,289,214, 1 gene, copy number 9: RNY1P5.
- chr13:75,109,587–75,109,693, 1 gene, copy number 11: RNU6-38P.
- chr13:75,871,038–76,135,225, 5 genes, copy number 7–9: LMO7DN, LMO7DN-IT1, LINC00561, LINC01034, RN7SL571P.
- chr13:105,459,055–110,561,722, 60 genes, copy number 7–17: DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, RNA5SP38, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL162574.2, PPIAP24, AL162574.1, AL162574.3, FAM155A, SNORD31B, AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20.
- chr14:32,879,246–33,804,176, 4 genes, copy number 5: AL049781.1, NPAS3, AL161851.1, AL161851.2.
- chr17:82,239,023–82,945,914, 40 genes, copy number 5 (within-gene range 3–5): CSNK1D, AC132872.3, AC132872.4, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750, AC087222.1.
- chr19:17,049,729–18,000,080, 57 genes, copy number 6–9: HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3, MAP1S, AC008761.1, FCHO1, B3GNT3, INSL3, JAK3, RPL18A, SNORA68, AC005796.1, SLC5A5, CCDC124, KCNN1, RNA5SP468.
- chr19:27,638,483–30,038,181, 57 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.
- chr20:32,358,330–64,327,972, 804 genes, copy number 5 (broad region; genes not listed).
- chr21:7,744,962–8,701,562, 29 genes, copy number 8: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.
- chr21:19,739,709–19,900,043, 3 genes, copy number 5: SREK1IP1P1, C1QBPP1, LINC01683.

Autosomal genes at a single copy (total copy number 1): 44. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
